TCGA case TCGA-CZ-5466 — Kidney Renal Clear Cell Carcinoma (TCGA-KIRC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney; Tissue source site: Harvard. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/5722df9f-5631-476d-a11b-b3c1e9a40fbf

Demographics
Sex at birth: male; Age at index: 67 years; Vital status: Alive.

Diagnoses (1)
1. Clear cell adenocarcinoma, NOS: ICD-O-3 morphology code: 8310/3; ICD-10 code: C64.9; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 67.5 years (24,669 days); Year of diagnosis: 2007; AJCC staging edition: 6th; AJCC pathologic T: T3a; AJCC pathologic N: NX; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 685 days (1.9 years).
   Pathology details: Consistent pathology review: Yes.

Follow-up (2 entries)
- Days to follow up: 685 days (1.9 years); Disease response: Tumor Free.
- ECOG performance status: 0; Timepoint: Preoperative.

Molecular and laboratory tests
- Leukocytes: Elevated.
- Platelets: Normal.
- Calcium: Normal.
- Hemoglobin: Low.

Exposures
- Exposure type: Tobacco.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-CZ-5466-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.6; Intermediate dimension: 1.2; Shortest dimension: 0.3.
  Slide TCGA-CZ-5466-01A-01-TS1: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 75; Percent normal cells: 15; Percent necrosis: 0; Percent stromal cells: 10.
  Slide TCGA-CZ-5466-01A-01-BS1: Section location: Bottom; Percent tumor cells: 72; Percent tumor nuclei: 75; Percent normal cells: 18; Percent necrosis: 0; Percent stromal cells: 10.
- Sample TCGA-CZ-5466-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-CZ-5466-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1.2; Intermediate dimension: 1.1; Shortest dimension: 0.4.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Kidney Clear Cell Renal Carcinoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; Hemoglobin level: Low; Lymph nodes examined: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 685 days; disease-specific survival: no event (censored), 685 days; progression-free interval: no event (censored), 685 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-CZ-5466-01A-01D-1499-01): tumor purity 0.38, ploidy 2.16, whole-genome doublings 0.
